Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040033-09A.1 (aliquot TARGET-15-SJMPAL040033-09A.1-01D) from TARGET case TARGET-15-SJMPAL040033, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.4 years (5,242 days).
Specimen TARGET-15-SJMPAL040033-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9759cc6-cfe8-4f61-b67b-5b82098e5302.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040033-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040033-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a048c923-b4bd-4dd2-91c0-11477114ed86

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Intron 2, Silent 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.1328G>A p.R443K | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs199916575, COSV66069988; called by muse, mutect2, varscan2
- ASAP1 | c.1009G>T p.G337W | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100727956, COSV63048962; called by muse, mutect2, varscan2
- BCOR | c.1025G>T p.R342L | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100654395; called by muse, mutect2
- CACNA1H | c.5685C>A p.D1895E | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV52356542; called by muse, mutect2
- CD209 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as rs199960291; called by mutect2, varscan2
- ETV6 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1565546170, COSV67149864; called by muse, mutect2, varscan2
- FOXF1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as COSV52286961; called by muse, mutect2
- INSC | c.1688G>A p.R563Q | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs751225472; called by muse, varscan2
- NDST1 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs770142868; called by muse, mutect2, varscan2
- PLSCR4 | c.888C>A p.F296L | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61607453; called by muse, mutect2, varscan2
- SCML1 | c.643C>T p.R215W (on ENST00000380041 / NM_001037540.3; = p.R188W on NM_006746.6) | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV101193977; called by muse, mutect2, varscan2
- ZNF469 | c.5521C>T p.R1841W (on ENST00000437464; = p.R1869W on NM_001367624.2) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1292024809, COSV101458687; called by muse, mutect2, varscan2
- BRCA2 | c.3611C>A p.A1204D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- ITPRID1 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.8); called by muse, varscan2
- KRT32 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR7D2 | c.923C>A p.A308E | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.097); called by muse, mutect2
- PPAT | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2
- PYGM | c.1158G>T p.E386D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- SECTM1 | c.518G>T p.C173F | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.12); called by muse, mutect2
- TIA1 | c.901G>T p.G301* (on ENST00000433529 / NM_001351511.1; = p.G290* on NM_022037.4 and 9 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | called by muse, varscan2
- FEM1C | c.1563G>A p.V521= | Silent (SNP) | VAF 9/13 reads (69%) | called by muse, mutect2, varscan2
- URB2 | c.645C>A p.G215= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV50983949; called by muse, mutect2, varscan2
- MACF1 | c.15832-10967C>A | Intron (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- SACM1L | c.32+29C>A | Intron (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
